Somatic mutation profile of tumor specimen TCGA-CV-7446-01A (aliquot TCGA-CV-7446-01A-11D-2229-08) from TCGA case TCGA-CV-7446, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.2 years (24,170 days).
Specimen TCGA-CV-7446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccfdb1c-bc7a-44ae-8e03-84e3e8833f77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7446-10A (Blood Derived Normal), aliquot TCGA-CV-7446-10A-01D-2229-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ec90bf-30fe-41ca-a4a2-fd3cdbd42916

The open-access MAF lists 166 somatic variants for this specimen: 125 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 35, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 5, In Frame Del 3, Intron 3, 3'Flank 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765284825, CM050688, COSV99222427; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 149/163 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4089C>A p.N1363K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs1295742197, COSV99446958; called by muse, mutect2, varscan2
- ABCC2 | c.1569C>A p.D523E | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100966591; called by muse, mutect2
- ABCC2 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.062); catalogued as rs1477237225, COSV100966593; called by muse, mutect2
- ADAM11 | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV99567624; called by muse, mutect2, varscan2
- ATR | c.1778T>A p.M593K | Missense Mutation (SNP) | VAF 199/536 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100638360; called by muse, mutect2
- CALB1 | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55366923, COSV99617770; called by muse, mutect2, varscan2
- CCNB3 | c.1694T>C p.M565T | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1390404923, COSV99329334; called by muse, mutect2, varscan2
- CDH10 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 100/242 reads (41%) | catalogued as COSV100052094, COSV99072653; called by muse, mutect2, varscan2
- CDH12 | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101202845, COSV66406650; called by muse, mutect2, varscan2
- CFAP45 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as rs145313899, COSV100928620; called by muse, mutect2, varscan2
- CGREF1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as COSV53148545; called by muse, mutect2, varscan2
- CHAF1A | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as rs778336745, COSV56671337; called by muse, mutect2, varscan2
- CLSTN2 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs773695781, COSV71720927; called by muse, mutect2, varscan2
- CNTNAP4 | c.1637C>G p.S546* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100272189; called by muse, mutect2, varscan2
- CNTNAP5 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV101443769; called by muse, mutect2, varscan2
- COL14A1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as rs867973354, COSV52858729; called by muse, mutect2, varscan2
- COL17A1 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100793235; called by muse, mutect2, varscan2
- CPLX3 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.987); catalogued as COSV100547748; called by muse, mutect2, varscan2
- CSMD3 | c.10369A>G p.N3457D (on ENST00000297405 / NM_001363185.1; = p.N3288D on NM_052900.3) | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV52310925, COSV99838830; called by muse, mutect2, varscan2
- CYRIB | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV101310178; called by muse, mutect2, varscan2
- CYSLTR2 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56165994, COSV99935295; called by muse, mutect2, varscan2
- DDI1 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100159854; called by muse, mutect2, varscan2
- DUOX1 | c.3962T>G p.F1321C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368150; called by muse, mutect2, varscan2
- EGF | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99491127; called by muse, mutect2, varscan2
- ELF1 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.881); catalogued as rs368030828; called by muse, mutect2, varscan2
- EMC1 | c.2510C>A p.S837Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100916458; called by muse, mutect2, varscan2
- ENAM | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1439071550, COSV101253210; called by muse, mutect2, varscan2
- ESYT3 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs372599591; called by muse, mutect2, varscan2
- FANCL | c.471+2T>A p.X157_splice | Splice Site (SNP) | VAF 34/66 reads (52%) | catalogued as COSV99287710; called by muse, mutect2, varscan2
- FAT4 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.45); catalogued as COSV101272514; called by muse, mutect2, varscan2
- FBXO47 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as rs895899161; called by muse, mutect2
- FLOT1 | c.952-1G>C p.X318_splice | Splice Site (SNP) | VAF 67/235 reads (29%) | catalogued as COSV100899811; called by muse, mutect2, varscan2
- GALNT5 | c.1731G>C p.Q577H | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV52035594, COSV99375361; called by muse, mutect2, varscan2
- GNPTAB | c.2791T>A p.F931I | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100172120; called by muse, mutect2, varscan2
- GNPTAB | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV100172123; called by muse, mutect2, varscan2
- GRHL2 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99307300; called by muse, mutect2, varscan2
- GRID1 | c.2140A>C p.K714Q | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100024868; called by muse, mutect2, varscan2
- GRID2 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV99942854; called by muse, mutect2, varscan2
- HADH | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV100531412; called by muse, mutect2, varscan2
- HECW1 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770069189, COSV67821956; called by muse, mutect2, varscan2
- HOXD12 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as COSV101184304, COSV66832912; called by muse, mutect2, varscan2
- HPN | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99385198; called by muse, mutect2
- IGF2R | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100807679; called by muse, mutect2, varscan2
- IGSF11 | c.1022T>G p.L341W (on ENST00000393775 / NM_001015887.3; = p.L340W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/195 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.71); catalogued as COSV100677517; called by muse, mutect2, varscan2
- IGSF9 | c.1268G>T p.R423L (on ENST00000368094 / NM_001135050.2; = p.R407L on NM_020789.4) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV100829643; called by muse, mutect2, varscan2
- IMPG2 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs200993095, COSV99515900; called by muse, mutect2, varscan2
- KIF18A | c.2536G>A p.V846I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs748687672, COSV54185609; called by muse, mutect2, varscan2
- LAMA5 | c.7657G>T p.V2553L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV99440969; called by muse, mutect2, varscan2
- LGR4 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 118/140 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775456873, COSV64863660; called by muse, mutect2, varscan2
- LRP8 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs1469687263, COSV100036671; called by muse, mutect2, varscan2
- MAST3 | c.3304T>A p.S1102T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99445698; called by muse, mutect2, varscan2
- MBD4 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99959525; called by muse, mutect2, varscan2
- MELTF | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs767247101, COSV99586337; called by muse, mutect2
- MICAL2 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | catalogued as rs574255304, COSV99816662; called by muse, mutect2, varscan2
- MYH13 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 65/86 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV52838140; called by muse, mutect2, varscan2
- NAV3 | c.3541C>A p.P1181T | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV57067598; called by muse, mutect2, varscan2
- NDST3 | c.1812G>C p.Q604H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56628669, COSV99631046; called by muse, mutect2, varscan2
- NDUFA13 | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV99389150; called by muse, mutect2, varscan2
- NLRC4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs780092732, COSV100707442; called by muse, mutect2, varscan2
- NRK | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99688347; called by muse, mutect2, varscan2
- NRM | c.34del p.L12Sfs*74 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV51296541; called by mutect2, varscan2
- NSDHL | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100938672; called by muse, mutect2, varscan2
- OR12D2 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs866716023, COSV101011356; called by muse, mutect2
- OR4A5 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100157189; called by muse, mutect2, varscan2
- OR4A5 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.931); catalogued as COSV100157186; called by muse, mutect2, varscan2
- OR5K2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1451705717, COSV101415963, COSV101415972; called by muse, mutect2, varscan2
- PCDHA7 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100971616; called by muse, mutect2, varscan2
- PCDHA9 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV100969783; called by mutect2, varscan2
- PCDHB16 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781867191, COSV53374147; called by muse, mutect2, varscan2
- PDE1A | c.1457A>T p.Y486F | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.112); catalogued as COSV100115093; called by muse, mutect2, varscan2
- PDE3A | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV100762392; called by muse, mutect2, varscan2
- PEX19 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs770461028, COSV100926964; called by muse, mutect2, varscan2
- PLA2G4E | c.1668C>G p.F556L | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101268606, COSV68152064; called by muse, mutect2, varscan2
- PPP1R3A | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52881576; called by muse, mutect2, varscan2
- PRKDC | c.3521C>G p.A1174G | Missense Mutation (SNP) | VAF 135/242 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100041372; called by muse, mutect2, varscan2
- PRR23B | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs865792854, COSV100272136; called by muse, mutect2, varscan2
- RADX | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.558); catalogued as COSV100998868; called by mutect2, varscan2
- RERE | c.2167A>C p.S723R | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100556875; called by muse, mutect2, varscan2
- RIN2 | c.2156A>G p.K719R (on ENST00000255006 / NM_001242581.1; = p.K670R on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99657411; called by muse, mutect2, varscan2
- RLF | c.3299C>T p.S1100L | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV65652800; called by muse, mutect2, varscan2
- SATB2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs530118484, COSV53484308; ClinVar: uncertain significance; called by muse, mutect2
- SCN1B | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 165/312 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as rs778461222, COSV99386626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.4918G>T p.G1640W | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327508; called by muse, mutect2, varscan2
- SH3PXD2B | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 77/101 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV100288206; called by muse, mutect2, varscan2
- SLC25A33 | c.701T>A p.F234Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as COSV100235800; called by muse, mutect2, varscan2
- SLC25A37 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99264035; called by muse, mutect2, varscan2
- SLC35F1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 111/144 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100837799; called by muse, mutect2, varscan2
- SPATA31E1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs776106873, COSV100350680; called by muse, mutect2, varscan2
- SPEF2 | c.3637C>T p.R1213* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as rs754927785, COSV61544091; called by muse, mutect2, varscan2
- ST3GAL2 | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 32/264 reads (12%) | PolyPhen possibly damaging (0.78); catalogued as rs750947767, COSV100735609, COSV100735709; called by muse, mutect2, varscan2
- SYK | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs756535744, COSV101002549; called by muse, mutect2, varscan2
- SYNE1 | c.23263G>C p.E7755Q (on ENST00000367255 / NM_182961.4; = p.E7684Q on NM_033071.3) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV55043009; called by muse, mutect2, varscan2
- TEX10 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100887880; called by muse, mutect2, varscan2
- TLR5 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100643333; called by muse, mutect2, varscan2
- TRIML1 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100206135; called by muse, mutect2, varscan2
- TTN | c.20647G>A p.D6883N (on ENST00000591111; = p.D5956N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | PolyPhen benign (0.003); catalogued as COSV100619776; called by muse, mutect2, varscan2
- UBE2T | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767237410, COSV100937923; called by muse, mutect2, varscan2
- VWA2 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100073808; called by mutect2, varscan2
- WWP1 | c.334+2T>A p.X112_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99616715; called by muse, mutect2, varscan2
- ZBBX | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs773263807, COSV100284414, COSV56790879; called by muse, mutect2, varscan2
- ZDHHC4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs977295777, COSV100253888; called by muse, mutect2, varscan2
- ZNF233 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100492339; called by muse, mutect2, varscan2
- ZNF280D | c.2470A>G p.I824V | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs765841908, COSV99974722; called by muse, mutect2, varscan2
- ZNF30 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100340660; called by muse, mutect2, varscan2
- ZNF304 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99988712; called by muse, mutect2, varscan2
- ZNF429 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764139712, COSV100641970; called by muse, mutect2, varscan2
- ZNF43 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100731868; called by muse, mutect2, varscan2
- ZNF479 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100482856, COSV58640754; called by muse, mutect2, varscan2
- ZNF626 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV99391772; called by muse, mutect2, varscan2
- ZNF800 | c.341A>T p.N114I | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99758015; called by muse, mutect2
- AC024940.1 | n.5606G>A | Splice Region (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- AGL | c.110del p.P37Qfs*71 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- B3GNT3 | c.175_187del p.A59Pfs*50 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- BICRA | c.1597del p.H533Tfs*191 | Frame Shift Del (DEL) | VAF 65/165 reads (39%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.685_719del p.R229* | Frame Shift Del (DEL) | VAF 46/282 reads (16%) | called by mutect2, pindel
- COL22A1 | c.644_645del p.R215Pfs*4 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | called by pindel, varscan2
- EGR4 | c.593_595del p.P198del (on ENST00000545030; = p.P95del on NM_001965.4) | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- IGLV1-47 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SGSM1 | c.2472_2474del p.D824del (on ENST00000400359 / NM_001039948.4; = p.D763del on NM_133454.3) | In Frame Del (DEL) | VAF 21/37 reads (57%) | called by mutect2, pindel, varscan2
- SGSM3 | c.1446_1448del p.R484del | In Frame Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- SLC39A12 | c.1162del p.V388Sfs*61 | Frame Shift Del (DEL) | VAF 61/99 reads (62%) | called by mutect2, pindel, varscan2
- TPR | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TRIP11 | c.140-1_159delinsAC p.X47_splice | Splice Site (DEL) | VAF 20/32 reads (63%) | called by pindel, varscan2*
- ADAM17 | c.1698T>A p.V566= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as COSV100176358; called by muse, mutect2, varscan2
- ASPG | c.411C>T p.V137= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV101496425; called by muse, mutect2, varscan2
- BACH1 | c.135C>T p.F45= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV54521082; called by muse, mutect2, varscan2
- BTBD7 | c.3129C>T p.A1043= | Silent (SNP) | VAF 71/275 reads (26%) | catalogued as COSV100597979; called by muse, mutect2, varscan2
- CCDC47 | c.135C>A p.V45= | Silent (SNP) | VAF 123/285 reads (43%) | catalogued as COSV99854230; called by muse, mutect2, varscan2
- CFAP70 | c.1068A>G p.R356= | Silent (SNP) | VAF 69/104 reads (66%) | catalogued as COSV100160770; called by muse, mutect2, varscan2
- COG8 | c.129G>A p.R43= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV99650811; called by muse, mutect2, varscan2
- DDX24 | c.1797C>T p.C599= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs1329784817, COSV100428025; called by muse, mutect2, varscan2
- DISP1 | c.4203G>C p.S1401= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99451414; called by muse, mutect2, varscan2
- FANCA | c.3531G>A p.L1177= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs886052482, COSV99235114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.12603C>G p.L4201= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV101499448; called by muse, mutect2, varscan2
- FAT1 | c.4305C>T p.T1435= | Silent (SNP) | VAF 82/167 reads (49%) | catalogued as COSV101499449; called by muse, mutect2, varscan2
- HAO1 | c.868C>T p.L290= | Silent (SNP) | VAF 46/203 reads (23%) | catalogued as COSV101113248; called by muse, mutect2, varscan2
- HCN3 | c.2256C>A p.A752= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as COSV100712954, COSV61361407; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1908C>T p.G636= | Silent (SNP) | VAF 104/114 reads (91%) | catalogued as COSV100781561; called by muse, mutect2, varscan2
- ISM1 | c.624C>G p.T208= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99340041; called by muse, mutect2, varscan2
- KLHL35 | c.1029C>T p.F343= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as rs776748022, COSV100888784; called by muse, mutect2, varscan2
- MEGF8 | c.2427C>G p.L809= (on ENST00000251268 / NM_001271938.2; = p.L742= on NM_001410.3) | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs1485845079, COSV99237483; called by muse, mutect2, varscan2
- MGAM | c.4371G>C p.L1457= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV101527579; called by muse, mutect2, varscan2
- MTHFD1 | c.1968C>G p.L656= | Silent (SNP) | VAF 58/119 reads (49%) | catalogued as COSV99387066; called by muse, mutect2, varscan2
- PDGFRL | c.924C>A p.I308= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs760546292, COSV99286500; called by muse, mutect2, varscan2
- PFKL | c.528C>T p.I176= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs747204872, COSV100827222; called by muse, mutect2, varscan2
- PLCH1 | c.1194C>T p.I398= (on ENST00000340059 / NM_001130960.2; = p.I410= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV58201484; called by muse, mutect2, varscan2
- RELN | c.3198G>A p.P1066= | Silent (SNP) | VAF 49/100 reads (49%) | catalogued as rs767180170, COSV100634141; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.3609C>T p.N1203= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs138943707; called by muse, mutect2, varscan2
- SGCG | c.90C>T p.G30= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54555305, COSV99523121; called by muse, mutect2, varscan2
- SH3D19 | c.1573C>T p.L525= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as COSV100455770; called by muse, mutect2, varscan2
- SOD2 | c.126C>T p.I42= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100496675; called by muse, mutect2, varscan2
- SPANXN2 | c.180T>C p.H60= | Silent (SNP) | VAF 58/71 reads (82%) | catalogued as COSV100979931; called by muse, mutect2, varscan2
- TFAP2A | c.1269C>T p.H423= (on ENST00000482890; = p.H415= on NM_001032280.3) | Silent (SNP) | VAF 446/600 reads (74%) | catalogued as rs745981703, COSV100117046, COSV60238751; called by muse, mutect2, varscan2
- UNC5D | c.672G>T p.S224= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54774144; called by muse, mutect2, varscan2
- WBP4 | c.153C>T p.S51= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV65274674; called by muse, mutect2, varscan2
- ZFAT | c.3180G>A p.L1060= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100914756; called by muse, mutect2, varscan2
- ZNF511 | c.507C>T p.H169= | Silent (SNP) | VAF 111/151 reads (74%) | catalogued as rs746532392, COSV100756833; called by muse, mutect2, varscan2
- ZNF699 | c.1470C>T p.L490= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100426997; called by muse, mutect2, varscan2
- C3P1 | n.2738G>A | RNA (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- CLASP1 | c.1912+2393C>T | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs113682265, COSV99755670; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37169003 G>A | 3'Flank (SNP) | VAF 81/175 reads (46%) | catalogued as rs760765344, COSV99950995; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446872 G>C | 3'Flank (SNP) | VAF 80/149 reads (54%) | called by muse, mutect2, varscan2
- MRC1 | c.917-167G>T | Intron (SNP) | VAF 30/42 reads (71%) | catalogued as COSV99519420; called by muse, mutect2, varscan2
- PLOD2 | c.1501-1020A>T | Intron (SNP) | VAF 65/456 reads (14%) | catalogued as COSV99282954; called by muse, mutect2, varscan2
